Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9R7, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9R7-01A (Primary Tumor).

SPECIMEN

1. Base of tumour
2. Bladder tumour

CLINICAL DETAILS

Bladder tumour (solid looking). TURT. Extensive necrotic infiltrating tumour.

MACROSCOPY

1. Three pieces of tissue, the largest 11mm, plus fragment.
2. 13g of soft friable tissue fragments.

MICROSCOPY

1 and 2.

Grade:

3, poorly differentiated

Growth pattern:

Solid

Type:

Transitional cell carcinoma

Muscularis propria:

Present

Stromal invasion:

Invasion of muscularis propria (pT2)

Vascular channel invasion:

Not identified

Background urothelium:

Flat urothelium is present which is not dysplastic.

SUMMARY

Bladder: Transitional cell carcinoma G3 pT2

CyCE *ICD O-3*
Carcinoma, urothelial NOS 8120/3
path *Carcinoma, transitional cell 8120/3*
Site: Bladder NOS C67.9
9/5/2/14

Source: NCI Genomic Data Commons file 62f09fd9-0ddc-4762-a75d-4d18a25c9d12 (TCGA-ZF-A9R7.4AC6F4EE-B501-4C35-B35A-576C03866311.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).